Somatic mutation profile of tumor specimen MP2PRT-PAPMRY-TMP1-A (aliquot MP2PRT-PAPMRY-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPMRY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,292 days).
Specimen MP2PRT-PAPMRY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ef35cf4-2979-4964-ab87-ea370d652654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPMRY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPMRY-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6708c4df-9ca5-408d-938d-eb4d8f3abb4d

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLHL12 | c.1105C>T p.R369* | Nonsense Mutation (SNP) | VAF 117/274 reads (43%) | catalogued as rs1050165622; called by muse, mutect2, varscan2
- SLC24A4 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs747743406, COSV100104091, COSV100104602; called by muse, mutect2, varscan2
- SMARCA4 | c.2897G>C p.R966P | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60803054; called by muse, mutect2, varscan2
- THBS2 | c.1922C>T p.T641M | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); catalogued as rs1451706316, COSV64679569; called by muse, mutect2, varscan2
- C1orf116 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 57/284 reads (20%) | called by muse, mutect2, varscan2
- DGKG | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 74/407 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2, varscan2
- PCDHB3 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 155/366 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAS2L2 | c.1293C>T p.D431= | Silent (SNP) | VAF 152/368 reads (41%) | catalogued as rs142059348; called by muse, mutect2, varscan2
- MUC5B | c.15000G>A p.S5000= | Silent (SNP) | VAF 142/326 reads (44%) | catalogued as rs371127122; called by muse, mutect2, varscan2
